Somatic mutation profile of tumor specimen TCGA-RD-A8N9-01A (aliquot TCGA-RD-A8N9-01A-12D-A397-08) from TCGA case TCGA-RD-A8N9, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 63.1 years (23,059 days).
Specimen TCGA-RD-A8N9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90cd583e-ee7d-45e5-9a2f-5bc0f38d7088.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RD-A8N9-10A (Blood Derived Normal), aliquot TCGA-RD-A8N9-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac58e722-16e5-49b6-b093-3bc4896a292f

The open-access MAF lists 134 somatic variants for this specimen: 88 protein-altering or splice-affecting, 44 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 44, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 1, 5'Flank 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.2074G>A p.V692I | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs561437854, COSV55897779; called by muse, mutect2, varscan2
- ANK2 | c.11525G>A p.R3842Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.01); catalogued as rs770954138, COSV100003250, COSV52157432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP10A | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.581); catalogued as rs780276499, COSV63522684; called by muse, mutect2, varscan2
- ATR | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100638481, COSV63386612; called by muse, mutect2, varscan2
- C5 | c.2096_2098del p.C699del | In Frame Del (DEL) | VAF 18/78 reads (23%) | catalogued as rs771790432; called by pindel, varscan2
- C5orf46 | c.215+1G>A p.X72_splice | Splice Site (SNP) | VAF 6/56 reads (11%) | catalogued as rs200286897; called by muse, mutect2
- CALCOCO1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.167); catalogued as rs763755443, COSV100017450; called by muse, mutect2, varscan2
- CCDC71 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.001); catalogued as rs1387523430, COSV100422421; called by muse, mutect2, varscan2
- CD44 | c.921C>A p.T307= | Splice Region (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99555955; called by muse, mutect2, varscan2
- CFAP91 | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142545565; called by muse, mutect2, varscan2
- CLASP2 | c.979A>C p.N327H | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100224123; called by muse, mutect2, varscan2
- CLCN5 | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs782720805, COSV100260332; called by muse, mutect2, varscan2
- CMYA5 | c.6051A>C p.E2017D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV101484283; called by muse, mutect2, varscan2
- CPLX3 | c.75T>A p.D25E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100547801; called by muse, mutect2
- CTNND2 | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100479973; called by muse, mutect2, varscan2
- CYP4A22 | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs536116490, COSV99595272; called by muse, mutect2, varscan2
- CYP4F2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV99686244; called by muse, varscan2
- DHTKD1 | c.1454A>G p.Y485C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as rs1017447763, COSV99536812; called by muse, mutect2, varscan2
- DMRT1 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs746758951, COSV101206705; called by muse, mutect2, varscan2
- DYNC1I1 | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs757671459, COSV100267663, COSV61467603; called by muse, mutect2
- EPHB3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV57806587; called by muse, mutect2
- FAM227B | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 59/186 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs199971746, COSV100175476; called by muse, mutect2, varscan2
- FBXW5 | c.674A>C p.Q225P | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV99812626; called by muse, mutect2, varscan2
- FCGBP | c.4307C>T p.P1436L | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs139250740; called by muse, mutect2, varscan2
- FMO4 | c.1449A>T p.R483S | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100882139; called by muse, mutect2, varscan2
- FZD7 | c.1467C>A p.Y489* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99637423; called by muse, mutect2, varscan2
- GOLGA3 | c.4003G>A p.A1335T | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV99212407; called by muse, mutect2, varscan2
- GRIA2 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52382550, COSV99645570; called by muse, mutect2, varscan2
- H2AC13 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV100704423; called by muse, mutect2, varscan2
- HERC4 | c.1990G>A p.V664I (on ENST00000395198 / NM_022079.3; = p.V656I on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.084); catalogued as COSV99517359; called by muse, mutect2, varscan2
- HOOK2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs1399930474, COSV99317798; called by muse, mutect2, varscan2
- KCNH6 | c.1620G>T p.Q540H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as COSV100121209; called by muse, mutect2, varscan2
- KIAA0100 | c.4796C>T p.S1599L | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101197382; called by muse, mutect2, varscan2
- KIR3DL1 | c.248G>T p.S83I | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV100428841; called by muse, mutect2, varscan2
- KLHL1 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100917937; called by muse, mutect2, varscan2
- KLHL36 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs749436389, COSV50718033; called by muse, mutect2, varscan2
- L3MBTL4 | c.969C>A p.D323E | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV53123723; called by muse, mutect2, varscan2
- LPGAT1 | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100878206; called by muse, mutect2
- LRRC37A | c.4282G>A p.A1428T | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1341086445, COSV100208238; called by muse, mutect2, varscan2
- LUZP2 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100420969, COSV61199599; called by muse, mutect2, varscan2
- MPG | c.62del p.K21Rfs*87 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | catalogued as rs1166802443; called by mutect2, varscan2
- MUC17 | c.11312G>A p.S3771N | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1389992037, COSV100074682; called by muse, mutect2, varscan2
- MUS81 | c.1031T>G p.I344S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138527502; called by muse, mutect2, varscan2
- MYO3A | c.3905A>G p.E1302G | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV99781053; called by muse, mutect2, varscan2
- NAP1L3 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100220587, COSV100220615; called by muse, mutect2, varscan2
- NBEA | c.8770G>C p.A2924P | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as rs1297578114, COSV100083130; called by muse, mutect2, varscan2
- NRG3 | c.992T>G p.F331C | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64543157; called by muse, mutect2, varscan2
- NUFIP1 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371806496; called by muse, mutect2, varscan2
- NUP205 | c.4009G>A p.G1337R | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754542120; called by muse, mutect2, varscan2
- OPRD1 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV99330469; called by mutect2, varscan2
- OR10K1 | c.310T>G p.F104V | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99193863; called by muse, mutect2, varscan2
- OR4C6 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV100051788; called by muse, mutect2
- OR4C6 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 92/201 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.976); catalogued as rs774797014, COSV58602768; called by muse, mutect2, varscan2
- OR4K15 | c.908C>T p.T303M (on ENST00000305051; = p.T279M on NM_001005486.1) | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs150969455, COSV59301119; called by muse, mutect2, varscan2
- OR5AS1 | c.575C>T p.T192I | Missense Mutation (SNP) | VAF 44/355 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV100546356; called by muse, mutect2, varscan2
- OR5R1 | c.9A>C p.E3D | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56572440, COSV56573131; called by muse, mutect2, varscan2
- OSBPL6 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as COSV99508235; called by muse, mutect2, varscan2
- PABPC3 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 38/190 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs778874181, COSV55798095; called by muse, varscan2
- PKHD1 | c.10613T>G p.I3538S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV100945090; called by muse, mutect2, varscan2
- PLCG1 | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759833563, COSV99719167; called by muse, mutect2, varscan2
- PPEF2 | c.1253G>T p.R418L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99714877; called by muse, mutect2, varscan2
- PRICKLE3 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99603040; called by muse, mutect2, varscan2
- PSG8 | c.1196C>A p.S399* | Nonsense Mutation (SNP) | VAF 49/363 reads (13%) | catalogued as COSV100126538; called by muse, mutect2, varscan2
- PTCHD3 | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV101438954; called by muse, mutect2, varscan2
- SLC12A5 | c.2408G>A p.R803H (on ENST00000454036 / NM_001134771.2; = p.R780H on NM_020708.5) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs779096129, COSV54793253; called by muse, mutect2, varscan2
- SLITRK4 | c.760A>G p.K254E | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.269); catalogued as COSV62023307; called by muse, mutect2, varscan2
- SMC1A | c.1430T>C p.L477P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100447638; called by muse, mutect2, varscan2
- SPTA1 | c.1901A>C p.K634T | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as COSV63752423, COSV63761847; called by muse, mutect2, varscan2
- STIL | c.1943G>T p.C648F | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54554431; called by muse, mutect2, varscan2
- TBC1D24 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs758665573, COSV53547192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TECR | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV53107647, COSV99295092; called by muse, mutect2, varscan2
- TM4SF4 | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV100541963; called by muse, mutect2, varscan2
- TNRC6A | c.4572T>A p.D1524E | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV100170378; called by muse, mutect2, varscan2
- TONSL | c.737T>A p.V246E | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.092); catalogued as COSV101340299; called by muse, mutect2, varscan2
- TP53 | c.927del p.N310Tfs*35 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as COSV53371983; called by mutect2, pindel, varscan2
- TRBJ2-1 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as rs1554511359; called by muse, mutect2, varscan2
- TSPYL6 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs746897592, COSV100336816, COSV57814785; called by mutect2, varscan2
- TTC14 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV99932296; called by muse, mutect2
- UNC13C | c.1614G>T p.Q538H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99521797, COSV99524339; called by muse, mutect2, varscan2
- VDAC3 | c.670A>C p.K224Q | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV50081872, COSV99195136; called by muse, mutect2
- VTN | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs782190887, COSV99412250; called by muse, mutect2, varscan2
- WFDC13 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs770984791, COSV57913786; called by muse, mutect2, varscan2
- WNT8A | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100843085; called by muse, mutect2, varscan2
- XRRA1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100370028; called by muse, mutect2, varscan2
- ZFYVE26 | c.7178G>C p.R2393P | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100720678; called by muse, mutect2, varscan2
- ZNF592 | c.706C>T p.R236* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100246051; called by muse, mutect2, varscan2
- MPG | c.60A>T p.Q20H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- OR4D10 | c.97_98del p.L33Gfs*19 | Frame Shift Del (DEL) | VAF 22/139 reads (16%) | called by mutect2, pindel, varscan2
- ARHGAP1 | c.1293C>T p.F431= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100358015; called by muse, mutect2, varscan2
- ASPG | c.1473C>T p.A491= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs1487890017, COSV101496434; called by muse, mutect2, varscan2
- ATP1B4 | c.504C>T p.N168= (on ENST00000218008 / NM_001142447.3; = p.N164= on NM_012069.5) | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as rs955969946, COSV54314410, COSV99486465; called by muse, mutect2, varscan2
- CCDC30 | c.2424G>A p.V808= (on ENST00000340612; = p.V765= on NM_001080850.3) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1206813156, COSV100501586; called by muse, mutect2, varscan2
- CFAP61 | c.3393C>T p.Y1131= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as rs775687199, COSV99845603, COSV99846192; called by muse, mutect2, varscan2
- CNR1 | c.153T>G p.T51= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100759287; called by muse, mutect2, varscan2
- CUBN | c.4269G>A p.T1423= | Silent (SNP) | VAF 23/105 reads (22%) | catalogued as rs758726713, COSV64721437; called by muse, mutect2, varscan2
- CYLC1 | c.190A>C p.R64= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV61411046, COSV61412380; called by muse, varscan2
- DCAF12L1 | c.57C>T p.D19= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV64422675; called by muse, mutect2, varscan2
- DENND1A | c.345C>A p.I115= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV101010769; called by muse, mutect2, varscan2
- DNAH5 | c.4182G>A p.L1394= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV54201126; called by muse, mutect2, varscan2
- DPY19L4 | c.2171G>A p.*724= | Silent (SNP) | VAF 41/317 reads (13%) | catalogued as COSV101363438; called by muse, mutect2, varscan2
- DSP | c.1818G>A p.R606= | Silent (SNP) | VAF 32/195 reads (16%) | catalogued as COSV101131634; called by muse, mutect2, varscan2
- EPPK1 | c.6268C>A p.R2090= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV101599931, COSV73260944, COSV73262304; called by muse, mutect2
- FPR3 | c.282C>A p.G94= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100200842; called by muse, mutect2
- FTMT | c.378G>A p.A126= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV58419830, COSV58420814; called by muse, mutect2, varscan2
- GLUD2 | c.582C>T p.T194= | Silent (SNP) | VAF 23/200 reads (12%) | catalogued as rs752231129, COSV100046910, COSV60151158; called by muse, mutect2, varscan2
- GRIA1 | c.1962G>A p.A654= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1270935592, COSV53620747; called by muse, mutect2, varscan2
- HCN1 | c.306G>T p.L102= | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100301682; called by muse, mutect2
- HECTD3 | c.597A>G p.A199= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV99870391; called by muse, mutect2, varscan2
- IGLV3-10 | c.222C>T p.S74= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as rs564956810; called by muse, mutect2, varscan2
- IRAG2 | c.4176T>A p.A1392= (on ENST00000636465; = p.A437= on NM_006152.4 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV100209628; called by muse, mutect2, varscan2
- ITM2B | c.762T>C p.F254= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as COSV101052364; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1483C>A p.R495= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as rs1296427170, COSV101198220; called by muse, mutect2, varscan2
- KRT25 | c.594G>A p.L198= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV100380025; called by muse, mutect2, varscan2
- LGSN | c.1062G>A p.A354= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as rs138743031; called by muse, mutect2, varscan2
- MICU3 | c.579A>G p.Q193= | Silent (SNP) | VAF 139/205 reads (68%) | catalogued as COSV100536514; called by muse, mutect2, varscan2
- MYO18B | c.7032G>A p.S2344= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs751381115, COSV100122252; called by muse, mutect2
- NMUR2 | c.213G>A p.L71= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99677211; called by muse, mutect2, varscan2
- OR10G7 | c.240G>T p.L80= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV100390027; called by muse, mutect2, varscan2
- OR8J3 | c.564T>G p.S188= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as COSV56882180; called by muse, mutect2, varscan2
- PCDHGA12 | c.561C>T p.D187= | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV52757297; called by muse, mutect2, varscan2
- PLSCR5 | c.708C>T p.F236= | Silent (SNP) | VAF 16/97 reads (16%) | catalogued as rs374815718; called by muse, mutect2, varscan2
- RAD51D | c.879G>A p.A293= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs368209468, CD155768; ClinVar: likely benign; called by muse, mutect2, varscan2
- RAD54L2 | c.3468C>T p.P1156= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as rs1367488744, COSV99621694; called by muse, mutect2, varscan2
- RYR1 | c.6393G>T p.L2131= | Silent (SNP) | VAF 27/49 reads (55%) | catalogued as rs759785005, COSV100616657; called by muse, mutect2, varscan2
- SCN1A | c.813C>A p.G271= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV100321579; called by muse, mutect2, varscan2
- SDK1 | c.1086C>T p.C362= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as rs752214798, COSV101269708, COSV67388623; called by muse, mutect2, varscan2
- SHROOM3 | c.4212G>A p.E1404= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99935072; called by muse, mutect2
- SIGLEC8 | c.996C>T p.N332= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as rs771076418, COSV58473511; called by muse, mutect2, varscan2
- TSKS | c.774G>A p.P258= | Silent (SNP) | VAF 14/19 reads (74%) | catalogued as rs757213011; called by muse, varscan2
- ZNF106 | c.828C>T p.D276= | Silent (SNP) | VAF 35/145 reads (24%) | catalogued as COSV99783010; called by muse, mutect2, varscan2
- ZNF468 | c.879T>C p.H293= | Silent (SNP) | VAF 30/208 reads (14%) | catalogued as COSV99700768; called by muse, mutect2, varscan2
- ZNF536 | c.3534C>T p.N1178= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs775487730, COSV100834707, COSV62836717; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302063 A>G | 5'Flank (SNP) | VAF 30/166 reads (18%) | catalogued as rs775249605; called by muse, mutect2, varscan2
- SNORD115-20 | n.23A>G | RNA (SNP) | VAF 70/371 reads (19%) | catalogued as rs376344032; called by muse, mutect2, varscan2
